Somatic mutation profile of tumor specimen 0DTGDC from CCDI case PBCJKZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.3 years (3,399 days).
Specimen 0DTGDC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 398828ca-6988-41a4-b727-eb81506b14a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTGDH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0258e5cd-f18a-470c-b9e5-0fefb2eb074e

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELF1 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 247/1251 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as rs1378908913, COSV53499805; called by muse, mutect2, varscan2
- FBRSL1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 48/1327 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1356075937, COSV55510719; called by muse, mutect2
- FPR1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 234/1296 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs139132326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPS2 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 176/676 reads (26%) | catalogued as rs1315430739; called by muse, mutect2, varscan2
- KNDC1 | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 21/670 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1409287666; called by muse, mutect2
- MUC1 | c.2816C>T p.A939V (on ENST00000611571 / NM_001371720.1; = p.A152V on NM_001204285.2) | Missense Mutation (SNP) | VAF 93/498 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1391725482; called by muse, mutect2, varscan2
- SDK2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 182/1289 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746724792, COSV66193172, COSV66197263; called by muse, mutect2, varscan2
- FAT3 | c.7289A>G p.E2430G | Missense Mutation (SNP) | VAF 124/993 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- KMT2C | c.9598G>T p.E3200* | Nonsense Mutation (SNP) | VAF 504/1021 reads (49%) | called by mutect2, varscan2
- PRB2 | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 237/1497 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PTGER2 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 38/906 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.029); called by muse, mutect2
- SHH | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 75/475 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SRRM1 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 212/1343 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NLRP7 | c.954C>T p.Y318= | Silent (SNP) | VAF 35/1448 reads (2%) | catalogued as COSV60171157; called by muse, mutect2
- PGA3 | c.105T>C p.R35= | Silent (SNP) | VAF 50/2060 reads (2%) | called by muse, mutect2
- TRIM9 | c.1603+40G>A | Intron (SNP) | VAF 136/622 reads (22%) | catalogued as rs748897524; called by muse, mutect2, varscan2
- ZNF589 | c.-30C>G | 5'UTR (SNP) | VAF 54/296 reads (18%) | called by muse, mutect2
